CCDI case PBCHND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/34daf0e7-afbf-4f75-ae87-d58485ade2f8

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar soft part sarcoma: ICD-O-3 morphology code: 9581/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.9 years (2,872 days).

Biospecimens (3 samples)
- Sample 0DSEYV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSEZ8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSEZK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
